Gene-level copy-number profile of tumor specimen ALCH-B39D-TTP1-A from ALCHEMIST case ALCH-B39D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,940 days).
Specimen ALCH-B39D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4bef6b59-ca42-44fe-bf6f-1d23bba2e44a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B39D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/41c7963a-ccba-4ca0-b9dc-c25561656a03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 560; copy number 1: 6,983; copy number 2: 50,135; copy number 3: 1,223.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,720,187–169,720,293, 1 gene: RNU6-637P.
- chr5:7,287,924–7,326,609, 3 genes (within-gene range 0–3): AC091951.2, AC091951.3, AC091951.1.
- chr6:163,363,210–163,363,463, 1 gene: AL031121.1.
- chr7:43,940,895–44,019,175, 6 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1.
- chr7:44,013,562–44,019,170, 1 gene (within-gene range 0–2): POLR2J4.
- chr7:77,071,751–77,072,237, 1 gene (within-gene range 0–2): AC007000.2.
- chr7:102,433,106–102,690,469, 20 genes (within-gene range 0–2): ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP.
- chr10:122,910,610–122,913,111, 1 gene: FAM24A.
- chr13:20,938,564–20,962,195, 3 genes: HNRNPA1P30, PPIAP27, RPSAP54.
- chr16:53,337,453–53,337,571, 1 gene: RNA5SP427.
- chr17:142,789–386,254, 5 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr19:24,098,425–24,147,081, 2 genes (within-gene range 0–2): BNIP3P40, AC073534.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
